Surgical pathology report (de-identified scan), TCGA case TCGA-HV-A5A3, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-A5A3-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS:

Solid pseudopapillary pancreas tumor R/O Ductal cell adenocarcinoma

Specimen : pancreas

GROSS:

Specimen status: Fresh

Operation: Radical distal pancreatectomy with splenectomy

Organs: Pancreas (11.5 x 6.1 x 4.0 cm) and spleen (10.6 x 6.1 x 3.1 cm and 144.0 gm)

Lesion: Pancreatic body mass

Size: 5.3 x 3.9 x 3.1 cm

Feature: Ill-defined, pale tan to beige, solid and firm mass

Resection margin: Abut to radial margin, 2.2 cm from proximal pancreatic margin

Remaining pancreatic parenchyma: Unremarkable

Other organ:

Spleen: Unremarkable

Representative sections submitted

Frozen section diagnosis

FS1, No. 8 lymph nodes: Metastatic adenocarcinoma (2/2)

FS2, Pancreatic resection margin: No tumor present

FS3, Posterior area of gastric wall: Tumor cell present

FS4, Gastroduodenal nodes: Metastatic carcinoma (1/1) with extranodal extension

Gross photo: Present

Blocks

T1-7, pancreatic mass x 7

P, remaining pancreatic parenchyma x 1

LN1-5, regional (peripancreatic) lymph nodes x 5

S1-2, spleen x 2

FS1-4, frozen permanent x 4

ICD-0-3

adenocarcinoma, duct, NOS 8500/3

Site: pancreas, body C25.1

fw
12/10/12

MICROSCOPIC:

Tumor type: Ductal adenocarcinoma

Differentiation: Moderately differentiated

[page 2 of 2]
Tumor location: Pancreas (body)

Extension: T3, Tumor extends beyond the pancreas

Tumor size: 5.3 x 3.9 x 3.1 cm

Lymphovascular invasion: Present

Perineural invasion: Present

Surgical margins: All surgical margins are free from tumor

DIAGNOSIS:

Pancreas, body, radical distal pancreatectomy:

Ductal adenocarcinoma, moderately differentiated, infiltrating

Lymph node, regional, peripancreatic, radical distal pancreatectomy:

Metastatic carcinoma, primary in pancreas (3/23)

Lymph node, regional, biopsy:

'No.8': Metastatic carcinoma, primary in pancreas (2/2)

'Gastroduodenal nodes': Metastatic carcinoma, primary in pancreas (1/1)
with extranodal extension

Tissue, labeled as 'posterior area of gastric wall', biopsy:

Tumor cell present

Spleen, splenectomy:

No pathologic abnormality

Source: NCI Genomic Data Commons file 438f093a-d239-4272-86dd-d3ad9c169f18 (TCGA-HV-A5A3.5576957F-3101-44C5-9CFB-AF8194453174.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).